Somatic mutation profile of tumor specimen MP2PRT-PAUWMA-TMP1-A (aliquot MP2PRT-PAUWMA-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUWMA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,708 days).
Specimen MP2PRT-PAUWMA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c2dd8a5-5caf-49c6-abe3-48db7a0e9655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUWMA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUWMA-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c9ff5ff-b914-477e-b339-6aa92840807e

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 23, Silent 13, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs104894365, CM061082, COSV55501342, COSV55883432; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 32/440 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- B3GNT4 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 153/352 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57336875; called by muse, mutect2, varscan2
- DMD | c.3928G>C p.E1310Q | Missense Mutation (SNP) | VAF 131/144 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV63790319; called by muse, mutect2, varscan2
- ELL2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.871); catalogued as rs373400145; called by muse, mutect2, varscan2
- NCOR2 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 174/416 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100656984; called by muse, mutect2, varscan2
- PRELID1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs758980479, COSV57462769; called by muse, mutect2, varscan2
- RNPEPL1 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 160/361 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs771870592; called by muse, mutect2, varscan2
- TCF7L1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 181/406 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs1157152409; called by muse, mutect2, varscan2
- WNK2 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 45/541 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs376197419; called by muse, mutect2
- ZNF425 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 138/319 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs762961010; called by muse, mutect2, varscan2
- AP2A1 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CPNE4 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEFA4 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 173/355 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLM2 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KLHL4 | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MFSD1 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCDHB4 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 36/786 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHB7 | c.2382A>T p.*794Cext*1 | Nonstop Mutation (SNP) | VAF 67/811 reads (8%) | called by muse, mutect2
- PJA2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 126/267 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRC2A | c.4997G>T p.C1666F | Missense Mutation (SNP) | VAF 225/514 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SCN1A | c.4504G>A p.E1502K (on ENST00000303395 / NM_001202435.3; = p.E1491K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SRFBP1 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 126/318 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STUB1 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- UHRF1 | c.428_430del p.A143_R144delinsG (on ENST00000612630 / NM_001290050.1; = p.A156_R157delinsG on NM_013282.4) | In Frame Del (DEL) | VAF 45/158 reads (28%) | called by pindel*, varscan2
- AP1G2 | c.2223C>T p.I741= | Silent (SNP) | VAF 88/233 reads (38%) | catalogued as COSV99846336; called by muse, mutect2, varscan2
- CALB1 | c.771T>C p.C257= | Silent (SNP) | VAF 50/227 reads (22%) | called by muse, mutect2, varscan2
- EVA1C | c.690G>A p.Q230= | Silent (SNP) | VAF 27/423 reads (6%) | catalogued as COSV55823093; called by muse, mutect2
- FUT7 | c.219C>T p.I73= | Silent (SNP) | VAF 31/611 reads (5%) | catalogued as rs371488334; called by muse, mutect2
- GBF1 | c.115C>T p.L39= | Silent (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- GRIK3 | c.1083C>T p.R361= | Silent (SNP) | VAF 115/253 reads (45%) | called by muse, mutect2, varscan2
- KCNG1 | c.573C>T p.S191= | Silent (SNP) | VAF 44/556 reads (8%) | called by muse, mutect2
- LRP4 | c.4422G>T p.R1474= | Silent (SNP) | VAF 189/241 reads (78%) | called by muse, mutect2, varscan2
- NUP210 | c.510C>T p.F170= | Silent (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- PPFIBP1 | c.1776C>G p.L592= (on ENST00000318304 / NM_177444.3; = p.L586= on NM_003622.4) | Silent (SNP) | VAF 91/202 reads (45%) | called by muse, mutect2, varscan2
- REM1 | c.417G>A p.E139= | Silent (SNP) | VAF 16/284 reads (6%) | catalogued as rs1328786243; called by muse, mutect2
- UBE2L6 | c.135C>T p.P45= | Silent (SNP) | VAF 98/207 reads (47%) | called by muse, mutect2, varscan2
- WAC | c.801A>C p.P267= | Silent (SNP) | VAF 147/351 reads (42%) | called by muse, mutect2, varscan2
